Gene-level copy-number profile of tumor specimen HCM-CSHL-0740-C18-06A from HCMI case HCM-CSHL-0740-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 66.8 years (24,398 days).
Specimen HCM-CSHL-0740-C18-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 274e3ff7-02c3-410c-948c-f35978025b6f.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0740-C18-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,236 have no estimate.
https://portal.gdc.cancer.gov/files/0363c2f9-8600-4173-b084-999355e55a10

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 29; copy number 1: 962; copy number 2: 21,480; copy number 3: 29,695; copy number 4: 4,870; copy number 5: 1,351.

Homozygous deletions (total copy number 0; autosomes only): 29 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:89,913,982–89,969,335, 6 genes: IGKV1D-33, IGKV1D-32, IGKV3D-31, IGKV2D-30, IGKV2D-29, IGKV1D-27.
- chr8:12,356,136–12,359,391, 1 gene: ZNF705CP.
- chr10:102,461,395–102,502,712, 3 genes: MFSD13A, ACTR1A, AL121928.1.
- chr17:46,503,946–46,509,339, 1 gene: RDM1P2.
- chr18:50,879,080–51,643,939, 11 genes (within-gene range 0–2): ME2, Y_RNA, ELAC1, AC091551.1, SMAD4, SRSF10P1, MEX3C, RNU1-46P, LINC01630, SS18L2P2, AC109315.1.
- chr18:59,761,558–59,778,989, 2 genes: RPS26P54, GLUD1P4.
- chr22:18,773,665–18,861,049, 5 genes (within-gene range 0–2): GGT3P, AC008132.2, E2F6P1, AC008132.1, BCRP7.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 958. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
